Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7401, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7401-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) TONGUE, DORSAL SURFACE MARGIN EXCISION: NEGATIVE FOR MALIGNANCY.
- 2) TONGUE, VENTRAL SURFACE MARGIN EXCISION: NEGATIVE FOR MALIGNANCY.
- 3) TONGUE, POSTERIOR SURFACE MARGIN EXCISION: NEGATIVE FOR MALIGNANCY.
- 4) TONGUE, ANTERIOR SURFACE MARGIN EXCISION: NEGATIVE FOR MALIGNANCY.
- 5) TONGUE, RIGHT VENTRAL, GLOSSECTOMY: MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 1.1 CM IN GREATEST DIMENSION, INVASIVE INTO SUBEPITHELIAL TISSUE AND SUPERFICIAL MUSCLE; NEGATIVE FOR LYMPHOVASCULAR OR PERINEURAL INVASION; ALL SURGICAL MARGINS NEGATIVE FOR MALIGNANCY (SEE COMMENT).
- 6) LYMPH NODES, RIGHT LEVEL I, EXCISION: 11 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 7) LYMPH NODES, RIGHT LEVEL II, EXCISION: 6 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 8) LYMPH NODES, RIGHT LEVEL III, EXCISION: 10 LYMPH NODES, NEGATIVE FOR MALIGNANCY.

Comment: These findings correspond to AJCC pathologic stage I (pT1,pN0, Mn/a).

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) dorsal surface margin; 2) ventral surface margin; 3) posterior surface margin; 4) anterior surface margin; 5) right ventral tongue/floor of mouth; 6)

[page 2 of 3]
right neck, level 1; 7) right neck level
II; 8: right neck level III

GROSS DESCRIPTION:

1) SOURCE: Dorsal Surface Margin

Received fresh is a 3.6 x 0.2 x 0.2 cm strip of pink-tan mucosa. One end is marked by the surgeon as the anterior tip. This end is inked blue and the specimen is submitted in its entirety for frozen section analysis.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Ventral Surface Margin

Received fresh is a 3.0 x 0.2 x 0.2 cm strip of pink-tan mucosa. One end of the specimen is marked by the surgeon as the anterior tip. This specimen is inked black and the specimen is submitted in its entirety for frozen section analysis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Posterior Surface Margin

Received fresh is a 2.2 x 0.2 x 0.2 cm strip of pink-tan mucosa. One end is marked by the surgeon as the dorsal end. This tip is inked black and the specimen is submitted in its entirety for frozen section analysis.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Anterior Surface Margin

Received fresh is a 1.7 x 0.3 x 0.3 cm length of pink-tan mucosa. One end of the specimen is marked as the dorsal end by the surgeon. This end is inked black. This specimen is submitted in its entirety for frozen section analysis.

Summary of sections: 4AFSC, 1/1.

5) SOURCE: Right Ventral Tongue/ Floor of mouth

Received fresh is a 3.2 x 2.8 x 1.1 cm fragment of pink-tan mucosa with underlying red-brown soft tissue. This specimen is oriented with a stitch along one side that marks the anterior per the surgeon. The mucosa is remarkable for a central white-tan exophytic lesion measuring 1.1 cm in greatest dimension. This specimen is inked in the following fashion: anterior, yellow; posterior, green; medial, red; lateral, blue and deep black. A portion of the tumor is given to research. Additional portions are stored in glutaraldehyde and in the -80 degree freezer. The specimen is then serially and representative sections are submitted.

Summary of sections: 5A, posterior margin, 2/1; 5B, anterior margin, 2/1; 5C, lateral margin, 2/1; 5E, medial margin, 2/1; 5C, remainder of mucosa with tumor, 3/1.

6) SOURCE: Right Neck Level I Lymph node

Received fresh is a specimen measuring 9.0 x 4.8 x 2.8 cm consisting of a submandibular gland, vessels, and yellow tan soft tissue. A search is made

[page 3 of 3]
of the soft tissue portion of the specimen for lymph nodes and all lymph nodes identified are submitted in their entirety.

Summary of sections: 6A-C, lymph node candidates, M/1 each; 6D, representative section of salivary gland, 1/1.

7) SOURCE: Right Neck Level II Lymph node

Received fresh is a single fragment of pink-tan soft tissue measuring 8.0 x 4.0 x 0.5 cm. A thorough search of this specimen is made for lymph nodes.

All lymph node candidates identified are submitted in their entirety.

Summary of sections: 7A-B, 5/1 each.

8) SOURCE: Right Neck Level III Lymph node

Received fresh is a single fragment of pink-tan soft tissue measuring 8.0 x 4.2 x 1.0 cm. A thorough search of this specimen was made for lymph nodes and all lymph node candidates identified are submitted in their entirety.

Summary of sections: 1A-C, M/1 each.

Dictated by

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Dorsal Surface Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

2) SOURCE: Ventral Surface Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

3) SOURCE: Posterior Surface Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

4) SOURCE: Anterior Surface Margin

FROZEN SECTION DIAGNOSIS: BENIGN.

Electronically signed by: , Attending Pathologist

Source: NCI Genomic Data Commons file d4f467e7-4fe4-4e3c-9cf4-9af925a00c26 (TCGA-CR-7401.F4743731-0F13-48F7-9B91-21E5A4516A63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).